Surgical pathology report (de-identified scan), TCGA case TCGA-LG-A9QC, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Hartford Hospital, specimen TCGA-LG-A9QC-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

LOCATION:
SUBMITTING MD:
CC:

DIAGNOSIS

#1-CHOLECYSTECTOMY: MILD CHRONIC CHOLECYSTITIS.

#2-LIVER, RIGHT LOBE, RESECTION: HEPATOCELLULAR CARCINOMA

Tumor type:	Hepatocellular Carcinoma
Number of tumors:	One main tumor mass, with multiple surrounding satellite lesions
Tumor size:	9 cm
Location (R or L lobe):	Right lobe
Tumor Necrosis:	Present, incomplete
Worst Tumor differentiation:	Grade 2
Infiltrative pattern:	Absent
Vascular Invasion:	Present
Hepatic capsule:	No extrahepatic invasion
Local extension:	Absent
Margins:	Negative
Multifocality:	Satellite lesions* present, multiple, up to 1.5 cm diameter
Other findings:	Adjacent hepatic parenchyma with areas of hemorrhage, hemosiderin deposition, reactive changes, and mild portal chronic inflammation.
ypTNM:	pT1 pNx

ICD-O 3
Carcinoma hepatocellular NOS 8170/3
Site: Liver 022.0
J21/27/14

#3-DIAPHRAGM, PARTIAL RESECTION: SEGMENT OF SKELETAL MUSCLE CONSISTENT WITH DIAPHRAGM WITH SURFACE FIBROUS ADHESIONS AND FOCAL GRANULATION TISSUE. NEGATIVE FOR MALIGNANCY.

#4-SEGMENT OF OMENTUM: BENIGN ADIPOSE TISSUE WITH FOCAL FIBROSIS, NEGATIVE FOR MALIGNANCY.

Electronically Signed Out

COMMENT

88309, 88304, 88305, 88329B, 88311

Clinical Diagnosis and History:

Liver cancer

Tissue(s) Submitted:

1: GALLBLADDER

[page 2 of 2]
- 2: RIGHT LOBE OF LIVER
3: SECTION OF DIAPHRAGM
4: SEGMENT OF OMENTUM

Gross Description:

Specimen #1 is received in formalin, labeled gallbladder, and consists of an 8.5 x 3.5 x 1.4 cm intact gallbladder with attached pink cystic duct exhibiting a 0.5 cm in diameter lumen. The serosa is gray-pink and smooth. Opening reveals approximately 15-20 cc of amber viscous bile. The wall averages 0.1 cm. The mucosa is tan-red and velvety. No choleliths are identified. Representative sections are submitted labeled 1A.

Specimen #2 is received fresh for intraoperative consultation, labeled right lobe of liver (tissue removal time), and consists of a 1,289-gram, 16 x 13.5 x 9.5 cm right lobe of liver exhibiting a focally retracted and nodular capsule associated with a foci of adhesions. The resection margin is inked blue and the specimen is serially sectioned to reveal a 9.1 x 9 x 6.8 cm lobulated mass exhibiting a variegated yellow-tan to hemorrhagic (approximately 20%) cut surface. The mass comes to within 1.6 cm of the blue inked resection margin. The above is related to the surgeon intraoperatively. The remaining parenchyma appears gross unremarkable, exhibiting a homogeneous mahogany surface. Representative normal and tumor are triaged per a depth and protocol. Representative sections are submitted as follows:

- 2B: tumor to closest blue inked resection margin
2C-2E: representative sections of tumor with blue inked capsular adhesions/calcifications and hemorrhage (after decalcification)
2F-2I: additional representative sections of variegated cut surface
2J: representative sections of normal liver parenchyma
2K-2O: periphery of tumor, question satellite lesions
2P-2T: Question vascular invasion of tumor.

Specimen #3 is received in formalin labeled section of diaphragm and consists of a 1.5 x 0.5 x 0.5 cm tan white tissue fragment exhibiting a focally granular cut surface. The tissue is bisected and entirely submitted labeled 3A.

Specimen #4 is received is received fresh labeled segment of omentum and consists of a 10.0 x 7.5 x 1.8 cm lobulated portion of omentum exhibiting focal cautery and erythema. Sectioning reveals no gross nodules. Representative sections are submitted labeled 4A-4B.

Intraoperative Consult Diagnosis

2A/ SURGICAL MARGIN GROSSLY NEGATIVE 1.6CM FROM THE TUMOR.

END OF REPORT

Criteria	hw 12/20/13	Yes	No

Source: NCI Genomic Data Commons file d657dfe2-fef8-45c6-9745-dbd699ab225f (TCGA-LG-A9QC.AD8045A1-61EA-4713-9C8D-9AF200DB1424.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).